Somatic mutation profile of tumor specimen MMRF_1310_1_BM_CD138pos (aliquot MMRF_1310_1_BM_CD138pos_T1_KAS5U_L00334) from MMRF case MMRF_1310, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.1 years (29,239 days).
Specimen MMRF_1310_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f48a825-ab0c-4713-b958-92ef8a2bc396.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1310_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1310_1_PB_Whole_C3_KAS5U_L00335; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be7468ad-035b-4557-9d95-18da6353e9d1

The open-access MAF lists 131 somatic variants for this specimen: 54 protein-altering or splice-affecting, 18 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 30, Silent 18, Intron 15, 5'Flank 5, 3'Flank 5, Nonsense Mutation 3, 5'UTR 3, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 100/236 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.11488G>A p.E3830K | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs1406909211, COSV52170971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD18B | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.29); catalogued as rs111814125; called by mutect2, varscan2
- CDH11 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51762283; called by muse, mutect2, varscan2
- CELSR3 | c.5789C>T p.A1930V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs201802683; called by muse, mutect2, varscan2
- CHST13 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV60043421; called by muse, mutect2
- DDA1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs372277903; called by muse, mutect2
- EPB41L3 | c.3190C>A p.H1064N | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100547912; called by muse, mutect2, varscan2
- FAM111B | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 129/385 reads (34%) | catalogued as COSV59113258; called by muse, mutect2, varscan2
- GLIS2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756369339; called by muse, mutect2, varscan2
- GP5 | c.1637T>G p.I546S | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100540979; called by muse, mutect2, varscan2
- HMG20B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 220/336 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs755433105, COSV99503155; called by muse, mutect2, varscan2
- IGLV3-1 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs376783127; called by muse, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, mutect2, varscan2
- LMO7 | c.4187C>T p.S1396L (on ENST00000357063; = p.S1077L on NM_005358.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs964080367, COSV58534555; called by muse, mutect2, varscan2
- OR4C13 | c.893A>T p.K298I | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV73648639; called by muse, mutect2, varscan2
- RPA4 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0.259); catalogued as COSV61264236; called by muse, mutect2, varscan2
- SLC25A41 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs374633020; called by muse, mutect2, varscan2
- SPHKAP | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs1241778703; called by muse, mutect2, varscan2
- SYT6 | c.962G>A p.R321H (on ENST00000610222 / NM_001366225.1; = p.R236H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs549305784, COSV65773471, COSV65774250; called by muse, mutect2, varscan2
- TENT5C | c.77A>G p.H26R | Missense Mutation (SNP) | VAF 137/140 reads (98%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1558007668; called by muse, mutect2, varscan2
- TMEM249 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868916420; called by muse, mutect2, varscan2
- YBX1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs776203733; called by muse, mutect2, varscan2
- ABCC11 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2
- ADGRB3 | c.1142C>A p.P381Q | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ARAP2 | c.4031T>C p.I1344T | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.145); called by muse, mutect2
- ASTN2 | c.3702C>A p.F1234L (on ENST00000313400 / NM_001365069.1; = p.F1183L on NM_014010.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AWAT1 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRD8 | c.1994G>A p.S665N (on ENST00000254900 / NM_139199.2; = p.S738N on NM_006696.4) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCKBR | c.171A>C p.R57S | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CEBPB | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- COL3A1 | c.2513C>G p.P838R | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DSEL | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 141/305 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM111B | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 68/238 reads (29%) | called by muse, mutect2, varscan2
- FAM111B | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM111B | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 142/442 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, varscan2
- FBXO41 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO41 | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 74/129 reads (57%) | called by muse, mutect2, varscan2
- GRIN2A | c.2737T>C p.S913P | Missense Mutation (SNP) | VAF 126/258 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV1-69D | c.312C>G p.S104R | Missense Mutation (SNP) | VAF 76/83 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, varscan2
- IL4R | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ISG20 | c.101A>G p.H34R | Missense Mutation (SNP) | VAF 169/262 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KAT7 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 140/254 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAD1L1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MAEL | c.649-1G>T p.X217_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- NBEAL2 | c.6146A>T p.Y2049F | Missense Mutation (SNP) | VAF 122/360 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NMRK1 | c.177dup p.A60Sfs*3 | Frame Shift Ins (INS) | VAF 33/126 reads (26%) | called by mutect2, pindel, varscan2
- PCDHA1 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 94/262 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PMPCB | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RBM26 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC26A6 | c.307A>T p.M103L | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SLIT2 | c.2443T>C p.C815R | Missense Mutation (SNP) | VAF 74/114 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SUGP2 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- USP45 | c.670A>T p.S224C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ACSM2A | c.870G>A p.K290= (on ENST00000219054; = p.K211= on NM_001308169.2) | Silent (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- CCR10 | c.1011C>T p.R337= | Silent (SNP) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- EEF1A2 | c.141T>C p.A47= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as rs779435066; called by muse, mutect2, varscan2
- EPHA1 | c.549C>T p.L183= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs759046453; called by muse, mutect2, varscan2
- FAM111B | c.894G>C p.L298= | Silent (SNP) | VAF 131/404 reads (32%) | called by muse, varscan2
- HERC1 | c.9249T>C p.D3083= | Silent (SNP) | VAF 6/158 reads (4%) | catalogued as rs1456725367; called by muse, mutect2
- KBTBD7 | c.1455T>C p.Y485= | Silent (SNP) | VAF 86/156 reads (55%) | called by muse, mutect2, varscan2
- KCNC3 | c.2250C>T p.N750= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs973174466, COSV65388314; called by muse, mutect2, varscan2
- KCTD8 | c.678C>T p.D226= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as rs760544672, COSV63587803; called by muse, mutect2, varscan2
- KEAP1 | c.1017C>A p.L339= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV99408377; called by muse, mutect2, varscan2
- LRRC14 | c.276G>T p.L92= | Silent (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- RBMXL2 | c.564C>T p.D188= | Silent (SNP) | VAF 59/60 reads (98%) | catalogued as rs1395537265; called by muse, mutect2, varscan2
- STX11 | c.696G>A p.A232= | Silent (SNP) | VAF 94/96 reads (98%) | catalogued as COSV62449814; called by muse, mutect2, varscan2
- TMEM236 | c.363C>T p.V121= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- TRIM46 | c.1791C>T p.A597= | Silent (SNP) | VAF 138/192 reads (72%) | catalogued as rs775830596, COSV100104577; called by muse, mutect2, varscan2
- TTC3 | c.3285T>C p.N1095= | Silent (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- UMOD | c.1251C>T p.L417= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1412107982; called by muse, mutect2, varscan2
- ZNF536 | c.3738G>A p.A1246= | Silent (SNP) | VAF 55/194 reads (28%) | catalogued as rs763122092, COSV62817654; called by muse, mutect2, varscan2
- ASAP2 | c.*1569A>T | 3'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as COSV53005749; called by muse, mutect2
- CELF2 | c.1075+102C>T | Intron (SNP) | VAF 36/67 reads (54%) | catalogued as rs182138883; called by muse, mutect2, varscan2
- CELSR1 | c.7760-11G>A | Intron (SNP) | VAF 77/158 reads (49%) | catalogued as rs750953300, COSV53091779; called by muse, mutect2, varscan2
- CHCHD10 | c.*80T>C | 3'UTR (SNP) | VAF 76/158 reads (48%) | called by muse, mutect2, varscan2
- CNNM4 | c.*2174C>T | 3'UTR (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- CSK | c.16-63T>A | Intron (SNP) | VAF 51/150 reads (34%) | called by muse, mutect2, varscan2
- DPY19L4 | c.-52G>A | 5'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- DUSP4 | c.*1683C>T | 3'UTR (SNP) | VAF 44/104 reads (42%) | catalogued as rs1271468686; called by muse, mutect2, varscan2
- ENTPD5 | chr14:73958513 A>G | 3'Flank (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- FSD1L | c.*4403T>A | 3'UTR (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- GMCL1 | c.*2001A>T | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- GPAT2P1 | chr2:95792169 G>A | 5'Flank (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- HEXB | c.1613+42A>G | Intron (SNP) | VAF 109/307 reads (36%) | called by muse, mutect2, varscan2
- HNRNPL | c.880+31T>C | Intron (SNP) | VAF 30/118 reads (25%) | catalogued as rs756738326; called by muse, mutect2, varscan2
- HSPB1P1 | n.131G>A | RNA (SNP) | VAF 22/86 reads (26%) | catalogued as rs927444220; called by muse, mutect2, varscan2
- JADE1 | c.*1173T>C | 3'UTR (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- KCNAB1 | c.572-13C>A | Intron (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- KCNE5 | c.*633A>G | 3'UTR (SNP) | VAF 5/138 reads (4%) | called by muse, mutect2
- LAMA4 | c.*69G>A | 3'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- MAP3K13 | c.*3664del | 3'UTR (DEL) | VAF 20/98 reads (20%) | called by mutect2, pindel*, varscan2
- MKRN2 | chr3:12584136 T>A | 3'Flank (SNP) | VAF 81/286 reads (28%) | called by muse, mutect2, varscan2
- NEFM | c.*422T>C | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- NEK1 | c.*172T>G | 3'UTR (SNP) | VAF 54/196 reads (28%) | called by muse, mutect2, varscan2
- NFKBIZ | c.1824+93_1824+96del | Intron (DEL) | VAF 20/77 reads (26%) | called by pindel, varscan2
- NIPAL2 | c.*2931T>C | 3'UTR (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- PCDH10 | c.-53A>G | 5'UTR (SNP) | VAF 63/87 reads (72%) | catalogued as rs202076989; called by muse, mutect2, varscan2
- PCDH10 | c.*664A>T | 3'UTR (SNP) | VAF 35/56 reads (63%) | called by muse, mutect2, varscan2
- PDRG1 | c.*431G>A | 3'UTR (SNP) | VAF 97/217 reads (45%) | called by muse, mutect2, varscan2
- PGAP1 | chr2:196927761 G>A | 5'Flank (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- PLXNA1 | c.*2856G>A | 3'UTR (SNP) | VAF 60/205 reads (29%) | called by muse, mutect2, varscan2
- PRLR | c.*7703T>A | 3'UTR (SNP) | VAF 100/143 reads (70%) | called by muse, mutect2, varscan2
- RABGEF1 | chr7:66811319 A>T | 3'Flank (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- RANGAP1 | c.*1018C>T | 3'UTR (SNP) | VAF 53/109 reads (49%) | catalogued as rs940482695; called by muse, mutect2, varscan2
- REG3G | c.-101C>G | 5'UTR (SNP) | VAF 11/119 reads (9%) | catalogued as COSV99709438; called by muse, mutect2
- SCN7A | c.*1492A>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2
- SECISBP2 | chr9:89363570 del T | 3'Flank (DEL) | VAF 58/187 reads (31%) | called by mutect2, pindel, varscan2
- SELENOI | c.57+538A>G | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SEMA5A | c.271-27602G>A | Intron (SNP) | VAF 10/116 reads (9%) | catalogued as rs547905666; called by muse, mutect2
- SEMA6D | c.*1868dup | 3'UTR (INS) | VAF 30/94 reads (32%) | catalogued as rs1244655013; called by mutect2, varscan2
- SERINC5 | c.1238+2372A>G | Intron (SNP) | VAF 89/290 reads (31%) | called by muse, mutect2, varscan2
- SERTM1 | c.*292G>A | 3'UTR (SNP) | VAF 5/65 reads (8%) | catalogued as rs996851535; called by muse, mutect2
- SGPL1 | c.615+975G>T | Intron (SNP) | VAF 107/232 reads (46%) | called by muse, mutect2, varscan2
- SLC26A6 | c.1134+133G>A | Intron (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- SLC36A1 | c.*1569C>T | 3'UTR (SNP) | VAF 54/166 reads (33%) | catalogued as rs566450971; called by muse, mutect2, varscan2
- SLFNL1 | c.-119+81G>C | Intron (SNP) | VAF 111/203 reads (55%) | called by muse, mutect2, varscan2
- SLMAP | c.1135+6945G>A | Intron (SNP) | VAF 24/38 reads (63%) | catalogued as COSV55845943; called by muse, mutect2, varscan2
- SRPX | chrX:38220888 G>C | 5'Flank (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2, varscan2
- SRRM4 | c.*558G>A | 3'UTR (SNP) | VAF 61/132 reads (46%) | called by muse, mutect2, varscan2
- STX1B | c.*84T>C | 3'UTR (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- TBCCD1 | chr3:186570312 T>A | 5'Flank (SNP) | VAF 101/260 reads (39%) | catalogued as rs1288893028; called by muse, mutect2, varscan2
- TNS1 | c.*3853G>A | 3'UTR (SNP) | VAF 126/225 reads (56%) | catalogued as rs766604139; called by muse, mutect2, varscan2
- TRIM2 | chr4:153337080 G>T | 3'Flank (SNP) | VAF 68/97 reads (70%) | called by muse, mutect2, varscan2
- TRPV3 | c.*1252C>T | 3'UTR (SNP) | VAF 6/86 reads (7%) | catalogued as COSV56796402; called by muse, mutect2
- TVP23B | c.*123_*125delinsC | 3'UTR (DEL) | VAF 140/494 reads (28%) | called by mutect2*, pindel, varscan2*
- UACA | c.*2312A>G | 3'UTR (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2, varscan2
- WDR7 | c.*1575T>C | 3'UTR (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- WDR74 | chr11:62839696 T>A | 5'Flank (SNP) | VAF 153/440 reads (35%) | called by muse, mutect2, varscan2
- YY1 | c.*1179_*1180dup | 3'UTR (INS) | VAF 68/164 reads (41%) | called by mutect2, pindel, varscan2
- ZWILCH | c.54-20C>T | Intron (SNP) | VAF 53/173 reads (31%) | catalogued as rs1360040263; called by muse, mutect2, varscan2
